CCDI case PBCTJR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/51060b7b-bcbe-4182-90d7-903b1d9b9863

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Myofibroblastic tumor, NOS: ICD-O-3 morphology code: 8825/1; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 4.9 years (1,793 days).

Biospecimens (3 samples)
- Sample 0DZHVV: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DZY66: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0E0A0H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
